Gene-level copy-number profile of tumor specimen ALCH-ADW5-TTP1-A from ALCHEMIST case ALCH-ADW5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,639 days).
Specimen ALCH-ADW5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4ac5218-2ac6-454d-8cc7-d0c6c03a6aef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADW5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/2997f22d-77ba-45ab-8bd6-c8056b51ccea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 245; copy number 2: 14,742; copy number 3: 4,517; copy number 4: 33,374; copy number 5: 2,429; copy number 6: 3,035; copy number 7: 311; copy number 8: 164; copy number 9: 17; copy number 10: 4; copy number 15: 13; copy number 23: 1; copy number 27: 3.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,034,519–9,381,269, 1 gene (within-gene range 0–1): AC108519.1.
- chr4:9,153,296–9,369,070, 27 genes: FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P, USP17L15, USP17L16P, USP17L17, USP17L18, USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P.
- chr4:9,483,718–9,498,066, 2 genes: OR7E85P, UNC93B7.
- chr7:32,951,426–32,951,656, 1 gene: AC083863.1.
- chr7:102,464,956–102,478,907, 4 genes: LRWD1, MIR5090, MIR4467, POLR2J.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr7:149,285,281–149,297,312, 1 gene (within-gene range 0–2): AC004890.2.
- chr7:149,714,781–149,833,979, 3 genes: KRBA1, ZNF467, SSPOP.
- chr12:113,149,858–113,159,276, 2 genes (within-gene range 0–2): CFAP73, Y_RNA.
- chr12:113,159,113–113,159,177, 1 gene (within-gene range 0–2): MIR7106.
- chr14:69,561,019–69,574,871, 2 genes: AL133445.1, CCDC177.
- chr20:32,449,755–32,453,607, 1 gene (within-gene range 0–4): AL034550.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 38 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:97,901,653–98,024,296, 4 genes, copy number 10: RPL7AP61, AL356580.1, IPO5, FTLP8.
- chr13:110,809,676–111,305,737, 16 genes, copy number 9: LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1.
- chr17:39,728,496–39,730,532, 1 gene, copy number 9 (within-gene range 4–9): MIEN1.
- chr19:29,268,976–29,824,312, 10 genes, copy number 15: AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 15–23: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 27: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
